Somatic mutation profile of tumor specimen ALCH-B3Z8-TTP1-A (aliquot ALCH-B3Z8-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3Z8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Mucinous adenocarcinoma; Age at diagnosis: 57.9 years (21,131 days).
Specimen ALCH-B3Z8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b361e03-350b-4990-9e77-adf1ba86a297.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3Z8-NB1-A (Blood Derived Normal), aliquot ALCH-B3Z8-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ad15336-8952-4e4a-82fb-9792cf920d78

The open-access MAF lists 332 somatic variants for this specimen: 226 protein-altering or splice-affecting, 68 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 186, Silent 68, Nonsense Mutation 24, Intron 14, RNA 12, Frame Shift Del 6, 5'UTR 5, Splice Site 4, 3'UTR 4, Splice Region 4, 5'Flank 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 121/424 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RALGAPB | c.2324G>T p.R775L | Missense Mutation (SNP) | VAF 144/625 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs758022116; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC5 | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 80/400 reads (20%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.449); catalogued as rs768974148; called by muse, mutect2, varscan2
- ADGRG7 | c.1046C>A p.S349* | Nonsense Mutation (SNP) | VAF 49/248 reads (20%) | catalogued as COSV56295106; called by muse, varscan2
- ALPK1 | c.1522G>T p.E508* | Nonsense Mutation (SNP) | VAF 45/234 reads (19%) | catalogued as COSV99452952; called by muse, mutect2, varscan2
- ASB14 | c.767C>A p.A256D | Missense Mutation (SNP) | VAF 59/294 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67467130; called by muse, mutect2, varscan2
- ATP13A5 | c.1805C>T p.S602L | Missense Mutation (SNP) | VAF 40/361 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149839711, COSV60868943; called by muse, mutect2, varscan2
- ATP8B3 | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749622913, COSV59541965; called by muse, mutect2, varscan2
- BARD1 | c.1202G>T p.S401I | Missense Mutation (SNP) | VAF 77/345 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV53614713; called by muse, mutect2, varscan2
- BASP1 | c.278C>G p.A93G | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV59474500; called by muse, varscan2
- CATIP | c.563G>T p.R188L | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs201618489; called by muse, mutect2, varscan2
- CCDC142 | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 61/229 reads (27%) | catalogued as rs766153035; called by muse, mutect2, varscan2
- CDC20B | c.1116C>A p.S372R | Missense Mutation (SNP) | VAF 202/903 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs748116618, COSV57055469; called by muse, mutect2, varscan2
- CDH17 | c.1612C>A p.P538T | Missense Mutation (SNP) | VAF 101/546 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1439035250; called by muse, mutect2, varscan2
- CHD8 | c.2867G>A p.R956H (on ENST00000646647 / NM_001170629.2; = p.R677H on NM_020920.4) | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67870014; called by muse, mutect2
- CHL1 | c.2521C>A p.R841S (on ENST00000397491 / NM_001253387.1; = p.R857S on NM_006614.4) | Missense Mutation (SNP) | VAF 54/245 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV56593157; called by muse, mutect2, varscan2
- CHRM2 | c.180C>G p.Y60* | Nonsense Mutation (SNP) | VAF 199/914 reads (22%) | catalogued as COSV57769059; called by muse, mutect2, varscan2
- CLCN1 | c.2210C>T p.A737V | Missense Mutation (SNP) | VAF 153/546 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV58370432; called by muse, mutect2, varscan2
- CSRNP3 | c.995C>A p.S332* | Nonsense Mutation (SNP) | VAF 29/408 reads (7%) | catalogued as COSV100086253, COSV58779451; called by muse, mutect2
- CYP11B1 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 56/698 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs544670837, COSV52824806, COSV52825753; called by muse, mutect2
- DIP2C | c.2158G>T p.G720W | Missense Mutation (SNP) | VAF 64/470 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1353993006; called by muse, mutect2, varscan2
- DNAH14 | c.5653G>A p.V1885I (on ENST00000445597; = p.V2425I on NM_001367479.1) | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.241); catalogued as rs1178201933; called by muse, mutect2, varscan2
- DOCK10 | c.5858C>G p.T1953R | Missense Mutation (SNP) | VAF 62/622 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV51393285; called by muse, mutect2
- EYA4 | c.896C>T p.T299I | Missense Mutation (SNP) | VAF 39/350 reads (11%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.462); catalogued as COSV62061844; called by muse, mutect2, varscan2
- FAM71D | c.687G>T p.R229S | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.01); catalogued as COSV61296690; called by muse, mutect2, varscan2
- FAM83E | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 70/422 reads (17%) | catalogued as COSV99320117; called by muse, mutect2, varscan2
- FLT4 | c.605T>A p.L202Q | Missense Mutation (SNP) | VAF 82/318 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.284); catalogued as COSV56101730; called by muse, mutect2, varscan2
- GH2 | c.346G>T p.V116L | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.122); catalogued as rs61764019; called by muse, mutect2, varscan2
- GLG1 | c.2855G>C p.G952A | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as COSV52665138; called by muse, mutect2
- GLI2 | c.2057G>T p.G686V (on ENST00000361492 / NM_001374353.1; = p.G703V on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.055); catalogued as COSV100082487; called by muse, mutect2, varscan2
- GLYATL2 | c.822G>T p.L274F | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1346137497, COSV54848818; called by muse, mutect2
- GPR6 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT tolerated (0.9); PolyPhen benign (0.02); catalogued as rs1004146420, COSV51573272; called by muse, mutect2
- HSD11B1 | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 137/833 reads (16%) | catalogued as COSV54827116; called by muse, mutect2, varscan2
- ISL2 | c.94A>T p.S32C | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.778); catalogued as rs1187322070; called by muse, mutect2, varscan2
- ITGA8 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 28/352 reads (8%) | catalogued as rs780146784, COSV100959125; called by muse, mutect2
- ITGB2 | c.842C>A p.P281H | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100185998; called by muse, mutect2, varscan2
- KATNIP | c.4367G>A p.R1456H | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1472103053; called by muse, mutect2, varscan2
- KIR2DL4 | c.313G>C p.D105H (on ENST00000396284; = p.D66H on NM_001080770.2) | Missense Mutation (SNP) | VAF 51/307 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.824); catalogued as COSV100610483; called by muse, mutect2, varscan2
- MAGEB18 | c.289A>G p.R97G | Missense Mutation (SNP) | VAF 114/496 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs750688629; called by muse, mutect2, varscan2
- MAL | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 86/478 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs577290749, COSV59432275; called by muse, varscan2
- MCM5 | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1313010069; called by muse, mutect2, varscan2
- MTSS1 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs143535407; called by muse, mutect2, varscan2
- MTUS2 | c.667del p.H223Tfs*62 | Frame Shift Del (DEL) | VAF 54/214 reads (25%) | catalogued as COSV70919511; called by mutect2, pindel, varscan2
- NRAP | c.4277C>A p.A1426E (on ENST00000359988 / NM_001322945.2; = p.A1391E on NM_006175.4) | Missense Mutation (SNP) | VAF 78/776 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs751612141; called by muse, mutect2
- OCA2 | c.1213G>T p.G405* | Nonsense Mutation (SNP) | VAF 33/295 reads (11%) | catalogued as COSV62358662; called by muse, mutect2, varscan2
- OR10H4 | c.406C>T p.L136F | Missense Mutation (SNP) | VAF 74/258 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as rs759049418, COSV59063276; called by muse, mutect2, varscan2
- OR2L2 | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV100824421; called by muse, mutect2, varscan2
- OR4D10 | c.889G>C p.A297P | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101596988; called by muse, mutect2, varscan2
- PADI6 | c.1922G>A p.C641Y | Missense Mutation (SNP) | VAF 71/463 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100639973; called by muse, mutect2, varscan2
- PCDHB8 | c.1872G>T p.E624D | Missense Mutation (SNP) | VAF 200/930 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs782097283; called by muse, mutect2, varscan2
- PCSK7 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 38/280 reads (14%) | SIFT tolerated (0.62); PolyPhen probably damaging (1); catalogued as rs1451365335; called by muse, mutect2, varscan2
- POTEF | c.402C>A p.H134Q | Missense Mutation (SNP) | VAF 149/777 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.368); catalogued as rs200168896, COSV104417597, COSV62545047; called by muse, mutect2, varscan2
- PPP2R1A | c.1303G>T p.G435* | Nonsense Mutation (SNP) | VAF 70/329 reads (21%) | catalogued as COSV59042399; called by muse, mutect2, varscan2
- PRKDC | c.3732dup p.R1245Sfs*41 | Frame Shift Ins (INS) | VAF 51/314 reads (16%) | catalogued as rs751241508; called by mutect2, pindel, varscan2
- PRSS35 | c.1189G>T p.A397S | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764955895, COSV63800944; called by mutect2, varscan2
- RIMS2 | c.1304C>A p.T435N (on ENST00000666250 / NM_001348490.2; = p.T243N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/349 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs776368899; called by muse, mutect2, varscan2
- RPL10L | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 68/594 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs193920822, COSV53559621; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.3091C>A p.R1031S | Missense Mutation (SNP) | VAF 42/331 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as COSV100771770; called by muse, mutect2, varscan2
- RYR3 | c.7283C>G p.A2428G (on ENST00000389232; = p.A2429G on NM_001036.6) | Missense Mutation (SNP) | VAF 66/854 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV66803891; called by muse, mutect2
- SCAMP1 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 39/332 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.251); catalogued as rs902907367, COSV57241550; called by muse, mutect2, varscan2
- SCN9A | c.5167G>T p.G1723* (on ENST00000303354; = p.G1712* on NM_002977.3) | Nonsense Mutation (SNP) | VAF 56/568 reads (10%) | catalogued as rs1553473142; called by muse, mutect2
- SH3TC1 | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 24/438 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as rs532219231, COSV55286204; called by muse, mutect2
- SIGLEC9 | c.509G>T p.C170F | Missense Mutation (SNP) | VAF 74/452 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51583389; called by muse, mutect2, varscan2
- SLC10A5 | c.903C>A p.F301L | Missense Mutation (SNP) | VAF 53/337 reads (16%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV72828213; called by muse, mutect2, varscan2
- SLC35F1 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 22/197 reads (11%) | catalogued as COSV64501537; called by muse, mutect2, varscan2
- SPEG | c.6351G>T p.Q2117H | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.135); catalogued as rs868068713; called by muse, mutect2, varscan2
- SPTA1 | c.3743G>T p.R1248L | Missense Mutation (SNP) | VAF 61/422 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV63753987; called by muse, mutect2, varscan2
- SULF2 | c.1679G>A p.R560Q | Missense Mutation (SNP) | VAF 68/554 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs763594694, COSV63413635; called by muse, varscan2
- TBL1X | c.1505C>T p.T502M | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as COSV54273894; called by muse, mutect2, varscan2
- THEMIS | c.628del p.D210Tfs*14 | Frame Shift Del (DEL) | VAF 16/156 reads (10%) | catalogued as COSV100965641; called by mutect2, pindel, varscan2
- TMPRSS6 | c.1841G>T p.S614I | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.948); catalogued as CM1411676, CS097890, COSV60983612; called by muse, mutect2, varscan2
- TP53 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 143/494 reads (29%) | catalogued as COSV52679869, COSV53267121, COSV53424574; called by muse, mutect2, varscan2
- TRHR | c.427A>T p.K143* | Nonsense Mutation (SNP) | VAF 285/1243 reads (23%) | catalogued as COSV61233337; called by muse, mutect2, varscan2
- TSHR | c.928C>A p.R310S | Missense Mutation (SNP) | VAF 107/431 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.242); catalogued as rs121908882, CM002872, COSV53318872; called by muse, mutect2, varscan2
- TSPAN32 | c.863C>A p.A288E | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.031); catalogued as rs753797693; called by muse, mutect2, varscan2
- VSTM2A | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 26/873 reads (3%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.727); catalogued as COSV56497894; called by muse, mutect2
- VWA1 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 85/199 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.427); catalogued as rs1272887424; called by muse, mutect2, varscan2
- WT1 | c.1474C>T p.Q492* | Nonsense Mutation (SNP) | VAF 257/1026 reads (25%) | catalogued as COSV60073936; called by muse, mutect2, varscan2
- ZCCHC4 | c.1029T>A p.H343Q | Missense Mutation (SNP) | VAF 44/269 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs992974927; called by muse, mutect2, varscan2
- ZIM2 | c.477G>A p.Q159= | Splice Region (SNP) | VAF 33/162 reads (20%) | catalogued as COSV55627921, COSV99686814; called by muse, mutect2, varscan2
- ZNF211 | c.1367G>T p.G456V (on ENST00000347302 / NM_198855.4; = p.G469V on NM_006385.5) | Missense Mutation (SNP) | VAF 149/693 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV99560206; called by muse, mutect2, varscan2
- ZNF28 | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 54/333 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV60425166; called by muse, mutect2, varscan2
- ZNF292 | c.3548A>G p.Q1183R | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as rs781577339; called by muse, mutect2
- ZNF524 | c.151C>A p.P51T | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV55607260; called by muse, mutect2, varscan2
- ZNF536 | c.28G>T p.V10L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV62826236; called by muse, mutect2
- ACVR2A | c.36_39del p.F12Lfs*61 | Frame Shift Del (DEL) | VAF 78/543 reads (14%) | called by pindel, varscan2
- ADGRB3 | c.681G>T p.E227D | Missense Mutation (SNP) | VAF 30/244 reads (12%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.899); called by muse, varscan2
- ADGRE2 | c.920C>A p.A307E | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- AFAP1L1 | c.1744G>T p.A582S | Missense Mutation (SNP) | VAF 74/350 reads (21%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- AGBL2 | c.1588G>C p.E530Q | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- ALDH1A3 | c.71T>A p.I24N | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ARHGEF6 | c.1966G>T p.D656Y | Missense Mutation (SNP) | VAF 206/984 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATRNL1 | c.1387A>G p.I463V | Missense Mutation (SNP) | VAF 25/278 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- BAHCC1 | c.2682G>T p.M894I | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, varscan2
- BCL6B | c.415G>T p.G139C | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- BPNT1 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 122/769 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1B | c.6599G>A p.S2200N | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- CASR | c.2453C>A p.S818Y (on ENST00000490131; = p.S895Y on NM_000388.4) | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- CD5 | c.597C>G p.F199L | Missense Mutation (SNP) | VAF 27/383 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CDH9 | c.1281G>T p.M427I | Missense Mutation (SNP) | VAF 25/286 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.024); called by muse, mutect2
- CDYL | c.10C>A p.Q4K | Missense Mutation (SNP) | VAF 98/394 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD8 | c.1076C>A p.S359* (on ENST00000646647 / NM_001170629.2; = p.S80* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 33/649 reads (5%) | called by muse, mutect2
- CNGA2 | c.792_793del p.E264Dfs*7 | Frame Shift Del (DEL) | VAF 48/215 reads (22%) | called by pindel, varscan2
- COL4A5 | c.3186del p.G1063Afs*89 | Frame Shift Del (DEL) | VAF 130/640 reads (20%) | called by mutect2, pindel, varscan2
- COL6A1 | c.1462G>T p.G488C | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A3 | c.5659G>A p.V1887M | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CSRNP3 | c.1478A>G p.Y493C | Missense Mutation (SNP) | VAF 91/588 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CYP11A1 | c.305T>C p.I102T | Missense Mutation (SNP) | VAF 30/307 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); called by muse, mutect2
- DELE1 | c.459G>T p.R153S | Missense Mutation (SNP) | VAF 53/254 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- DGKB | c.1535T>A p.V512E | Missense Mutation (SNP) | VAF 58/345 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- DOCK4 | c.4380G>T p.K1460N | Missense Mutation (SNP) | VAF 96/448 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- DOT1L | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF2S2 | c.835G>A p.V279I | Missense Mutation (SNP) | VAF 188/752 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- EIF5B | c.851A>T p.K284I | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- ELAVL1 | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 59/573 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHA5 | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2
- EPRS1 | c.2725G>T p.A909S | Missense Mutation (SNP) | VAF 100/505 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- F13A1 | c.1748-2A>T p.X583_splice | Splice Site (SNP) | VAF 156/783 reads (20%) | called by muse, mutect2, varscan2
- FAM86B2 | c.892G>T p.G298C | Missense Mutation (SNP) | VAF 160/677 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- FAM90A14P | c.722C>A p.P241H | Missense Mutation (SNP) | VAF 117/1011 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FANCI | c.3052A>T p.S1018C (on ENST00000310775 / NM_001376911.1; = p.S958C on NM_018193.3) | Missense Mutation (SNP) | VAF 51/390 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- FBLN1 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 43/380 reads (11%) | called by muse, mutect2, varscan2
- GCLC | c.1822A>G p.N608D (on ENST00000643939; = p.N606D on NM_001498.4) | Missense Mutation (SNP) | VAF 33/808 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- GJB7 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 93/796 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- GLRA2 | c.343G>T p.D115Y | Missense Mutation (SNP) | VAF 62/645 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2
- GLS2 | c.1047+4dup | Splice Region (INS) | VAF 44/251 reads (18%) | called by mutect2, pindel, varscan2
- GORASP2 | c.457A>G p.I153V | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- GPR1 | c.830A>T p.Y277F | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- GREB1 | c.1403G>T p.R468L | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- GRIN2B | c.3711G>T p.Q1237H | Missense Mutation (SNP) | VAF 82/391 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- GTPBP8 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 18/63 reads (29%) | called by muse, mutect2, varscan2
- HIF1AN | c.381G>T p.E127D | Missense Mutation (SNP) | VAF 42/372 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HLA-DMA | c.373+6G>T | Splice Region (SNP) | VAF 37/143 reads (26%) | called by muse, mutect2
- HPS5 | c.3256G>T p.G1086C (on ENST00000349215 / NM_181507.2; = p.G972C on NM_007216.4) | Missense Mutation (SNP) | VAF 122/425 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- IFI44L | c.577G>T p.D193Y | Missense Mutation (SNP) | VAF 85/314 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- IGKV1-12 | c.332A>C p.Q111P | Missense Mutation (SNP) | VAF 80/2356 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2
- IGSF9 | c.315G>T p.W105C | Missense Mutation (SNP) | VAF 61/351 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- IMMP1L | c.79T>A p.F27I | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.085); called by muse, mutect2
- INPP5D | c.383C>A p.P128Q (on ENST00000445964 / NM_001017915.3; = p.P127Q on NM_005541.5) | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- JAG1 | c.887-1G>C p.X296_splice | Splice Site (SNP) | VAF 123/689 reads (18%) | called by muse, mutect2, varscan2
- JAKMIP1 | c.2357A>T p.E786V | Missense Mutation (SNP) | VAF 82/320 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCNB2 | c.2470G>T p.E824* | Nonsense Mutation (SNP) | VAF 69/460 reads (15%) | called by muse, mutect2, varscan2
- KCNK2 | c.963G>T p.E321D (on ENST00000444842 / NM_001017425.3; = p.E306D on NM_014217.4) | Missense Mutation (SNP) | VAF 47/284 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KIAA2012 | c.485T>A p.L162Q | Missense Mutation (SNP) | VAF 42/299 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- KIF3A | c.1228+1G>A p.X410_splice | Splice Site (SNP) | VAF 36/261 reads (14%) | called by muse, mutect2, varscan2
- KLHL6 | c.371A>G p.H124R | Missense Mutation (SNP) | VAF 68/383 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KLK15 | c.81G>T p.E27D | Missense Mutation (SNP) | VAF 64/330 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KRT1 | c.1329G>T p.K443N | Missense Mutation (SNP) | VAF 138/682 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT74 | c.1498A>T p.T500S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.039); called by muse, varscan2
- LCE3B | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 176/470 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- LEF1 | c.631C>A p.L211I | Missense Mutation (SNP) | VAF 62/556 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.167); called by mutect2, varscan2
- LGI4 | c.794-6C>A | Splice Region (SNP) | VAF 43/207 reads (21%) | called by muse, mutect2, varscan2
- LRFN2 | c.570G>T p.E190D | Missense Mutation (SNP) | VAF 123/567 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- LRP1B | c.5523C>A p.N1841K | Missense Mutation (SNP) | VAF 54/339 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- LRRTM4 | c.240G>T p.Q80H | Missense Mutation (SNP) | VAF 94/762 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- LTF | c.1202C>G p.A401G | Missense Mutation (SNP) | VAF 74/385 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.518); called by muse, mutect2
- MAGEB6 | c.617T>A p.L206Q | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAP3K19 | c.2575C>A p.P859T | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- MARCHF10 | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 52/441 reads (12%) | called by muse, varscan2
- MARCHF4 | c.272G>T p.R91M | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- MFAP3 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 62/284 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- MFRP | c.147G>T p.E49D (on ENST00000449574; = p.E425D on NM_031433.4) | Missense Mutation (SNP) | VAF 67/257 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- MINDY4 | c.1112A>T p.E371V | Missense Mutation (SNP) | VAF 105/597 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- MMP13 | c.1324T>C p.Y442H | Missense Mutation (SNP) | VAF 114/473 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC16 | c.16953G>T p.E5651D | Missense Mutation (SNP) | VAF 51/214 reads (24%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC5B | c.9664C>A p.L3222I | Missense Mutation (SNP) | VAF 69/579 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- MXI1 | c.191C>A p.T64N | Missense Mutation (SNP) | VAF 61/408 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MYH8 | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 31/998 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- MYO3A | c.3936G>T p.Q1312H | Missense Mutation (SNP) | VAF 18/299 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); called by muse, mutect2
- MYO3B | c.288C>A p.H96Q | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYOC | c.1322G>T p.S441I | Missense Mutation (SNP) | VAF 255/1103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- N4BP2 | c.5210G>A p.G1737E | Missense Mutation (SNP) | VAF 124/592 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEU4 | c.1261G>T p.D421Y (on ENST00000391969 / NM_001167602.3; = p.D433Y on NM_080741.4) | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NFRKB | c.3205G>A p.A1069T (on ENST00000446488 / NM_001143835.2; = p.A1094T on NM_006165.3) | Missense Mutation (SNP) | VAF 118/689 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- NGEF | c.813G>T p.E271D | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- NOS3 | c.1523C>T p.S508L | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- NPAP1 | c.1751C>A p.S584Y | Missense Mutation (SNP) | VAF 38/454 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- NRAP | c.4279C>G p.L1427V (on ENST00000359988 / NM_001322945.2; = p.L1392V on NM_006175.4) | Missense Mutation (SNP) | VAF 79/774 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2
- NUP98 | c.2365G>T p.D789Y | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OLFM4 | c.123C>A p.D41E | Missense Mutation (SNP) | VAF 116/529 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- OR10Z1 | c.219C>A p.Y73* | Nonsense Mutation (SNP) | VAF 56/252 reads (22%) | called by muse, mutect2, varscan2
- OR2T29 | c.12C>G p.I4M | Missense Mutation (SNP) | VAF 22/510 reads (4%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2
- OR2T5 | c.181A>T p.S61C | Missense Mutation (SNP) | VAF 36/336 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.195); called by mutect2, varscan2
- OR4C46 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 85/595 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PAX1 | c.969G>T p.W323C | Missense Mutation (SNP) | VAF 183/820 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDH8 | c.1944G>T p.E648D | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); called by muse, mutect2
- PIGT | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 56/414 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- PKHD1 | c.5290A>G p.N1764D | Missense Mutation (SNP) | VAF 278/1423 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- PNMA8B | c.1325G>T p.R442L | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- POLD1 | c.3071C>G p.A1024G | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); called by muse, mutect2
- POLR2H | c.95G>A p.S32N | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- PRAMEF2 | c.360G>T p.W120C | Missense Mutation (SNP) | VAF 69/689 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- PRDM5 | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 101/751 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- PRKAA2 | c.789-1G>T p.X263_splice | Splice Site (SNP) | VAF 12/38 reads (32%) | called by muse, varscan2
- RAB44 | c.68G>T p.R23I | Missense Mutation (SNP) | VAF 150/754 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RREB1 | c.821A>C p.N274T | Missense Mutation (SNP) | VAF 16/460 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- RSRC1 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.292); called by muse, mutect2
- RYR2 | c.13084G>T p.D4362Y | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- SCN2A | c.1942G>A p.V648M | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2
- SCN3A | c.4960G>T p.A1654S | Missense Mutation (SNP) | VAF 38/564 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.684); called by muse, mutect2
- SCN7A | c.1976A>T p.H659L | Missense Mutation (SNP) | VAF 96/502 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SEC16B | c.495G>T p.Q165H | Missense Mutation (SNP) | VAF 97/584 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SEC24A | c.1779G>T p.E593D | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- SLIT2 | c.2720G>T p.C907F | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOCS6 | c.303G>T p.E101D | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SON | c.1597G>T p.A533S | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- SP9 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 65/310 reads (21%) | called by muse, mutect2, varscan2
- SPTA1 | c.4634C>A p.A1545E | Missense Mutation (SNP) | VAF 141/795 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STX18 | c.524C>A p.T175K | Missense Mutation (SNP) | VAF 72/447 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TENM3 | c.5921C>A p.A1974E | Missense Mutation (SNP) | VAF 54/294 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- TLN2 | c.4941G>T p.K1647N | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM45B | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 43/393 reads (11%) | called by muse, mutect2, varscan2
- TMEM70 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 112/514 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- TMPRSS5 | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 62/214 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TNXB | c.10271C>A p.S3424Y (on ENST00000647633; = p.S3177Y on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/340 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- TYRP1 | c.39C>A p.F13L | Missense Mutation (SNP) | VAF 74/316 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- UGGT2 | c.2138dup p.D715Gfs*5 | Frame Shift Ins (INS) | VAF 20/86 reads (23%) | called by mutect2, pindel, varscan2
- ULK1 | c.303del p.D102Tfs*9 | Frame Shift Del (DEL) | VAF 31/139 reads (22%) | called by pindel, varscan2
- WDR72 | c.595A>T p.K199* | Nonsense Mutation (SNP) | VAF 20/326 reads (6%) | called by muse, mutect2
- WWC3 | c.1905C>A p.D635E | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- YPEL4 | c.23C>A p.P8Q | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFP91 | c.1146G>T p.K382N | Missense Mutation (SNP) | VAF 42/496 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- ZNF223 | c.1384G>T p.G462W | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF713 | c.897G>C p.K299N (on ENST00000633730 / NM_001366796.2; = p.K312N on NM_182633.3) | Missense Mutation (SNP) | VAF 43/266 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF844 | c.1317A>T p.K439N | Missense Mutation (SNP) | VAF 63/259 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- ZSCAN12 | c.1204A>G p.T402A | Missense Mutation (SNP) | VAF 87/415 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- AGMO | c.1317C>A p.L439= | Silent (SNP) | VAF 24/374 reads (6%) | called by muse, mutect2
- ANXA8 | c.960G>T p.L320= | Silent (SNP) | VAF 122/776 reads (16%) | called by muse, mutect2, varscan2
- AVEN | c.711A>C p.G237= | Silent (SNP) | VAF 33/344 reads (10%) | called by muse, mutect2
- C1QTNF4 | c.678C>T p.P226= | Silent (SNP) | VAF 24/236 reads (10%) | catalogued as rs1344275879; called by muse, mutect2
- C1orf131 | c.69C>G p.P23= | Silent (SNP) | VAF 55/327 reads (17%) | called by muse, mutect2, varscan2
- CATIP | c.564G>T p.R188= | Silent (SNP) | VAF 39/269 reads (14%) | called by muse, mutect2, varscan2
- CBLN4 | c.600C>A p.P200= | Silent (SNP) | VAF 150/420 reads (36%) | catalogued as rs1223046874; called by muse, mutect2, varscan2
- CCDC168 | c.2814A>G p.K938= | Silent (SNP) | VAF 53/275 reads (19%) | called by muse, mutect2, varscan2
- CCDC80 | c.621C>A p.G207= | Silent (SNP) | VAF 143/569 reads (25%) | called by muse, mutect2, varscan2
- CD22 | c.1569C>T p.N523= | Silent (SNP) | VAF 77/341 reads (23%) | called by muse, mutect2, varscan2
- CDH12 | c.300C>A p.T100= | Silent (SNP) | VAF 46/306 reads (15%) | catalogued as COSV66424241; called by muse, mutect2, varscan2
- CSMD1 | c.7236C>T p.R2412= (on ENST00000520002; = p.R2411= on NM_033225.6) | Silent (SNP) | VAF 50/345 reads (14%) | called by muse, mutect2, varscan2
- DAPP1 | c.318C>T p.V106= | Silent (SNP) | VAF 34/296 reads (11%) | called by muse, mutect2, varscan2
- EEF1A2 | c.453C>T p.G151= | Silent (SNP) | VAF 54/942 reads (6%) | catalogued as rs764827474; called by muse, mutect2
- EPHA8 | c.312C>A p.T104= | Silent (SNP) | VAF 41/252 reads (16%) | called by muse, mutect2, varscan2
- FAM71E2 | c.1032G>T p.T344= | Silent (SNP) | VAF 58/291 reads (20%) | called by muse, mutect2, varscan2
- FAP | c.447A>G p.P149= | Silent (SNP) | VAF 34/378 reads (9%) | called by muse, mutect2
- FARP2 | c.1383C>T p.L461= | Silent (SNP) | VAF 109/383 reads (28%) | catalogued as rs766057038, COSV99885144; called by muse, mutect2, varscan2
- FKBPL | c.441C>T p.G147= | Silent (SNP) | VAF 76/418 reads (18%) | catalogued as COSV64322384; called by muse, mutect2, varscan2
- FOXA2 | c.987G>T p.A329= (on ENST00000377115 / NM_153675.3; = p.A335= on NM_021784.5) | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs1490611006; called by muse, mutect2, varscan2
- GABRG1 | c.948G>T p.L316= | Silent (SNP) | VAF 54/240 reads (23%) | called by muse, varscan2
- GRIN3A | c.261G>T p.R87= | Silent (SNP) | VAF 20/89 reads (22%) | called by muse, mutect2, varscan2
- HECW1 | c.3687C>A p.A1229= | Silent (SNP) | VAF 129/663 reads (19%) | called by muse, mutect2, varscan2
- HOXD4 | c.114C>T p.G38= | Silent (SNP) | VAF 78/325 reads (24%) | catalogued as rs770140508; called by muse, mutect2, varscan2
- IGLV9-49 | c.237G>T p.G79= | Silent (SNP) | VAF 35/181 reads (19%) | called by muse, mutect2, varscan2
- IRX6 | c.240T>A p.A80= | Silent (SNP) | VAF 35/282 reads (12%) | called by muse, mutect2, varscan2
- ITSN1 | c.3504G>C p.A1168= | Silent (SNP) | VAF 10/85 reads (12%) | called by mutect2, varscan2
- KCNQ2 | c.867C>T p.N289= | Silent (SNP) | VAF 150/924 reads (16%) | catalogued as rs749934609, COSV60434788; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNQ3 | c.2526G>A p.T842= | Silent (SNP) | VAF 105/732 reads (14%) | catalogued as rs749906898, COSV66466837; called by muse, mutect2, varscan2
- KRTAP10-2 | c.402C>T p.S134= | Silent (SNP) | VAF 101/744 reads (14%) | catalogued as rs782545109; called by muse, mutect2, varscan2
- L3MBTL3 | c.735A>T p.A245= | Silent (SNP) | VAF 36/384 reads (9%) | called by muse, mutect2
- LAMB1 | c.2628C>T p.C876= | Silent (SNP) | VAF 125/453 reads (28%) | catalogued as rs369235660; called by muse, mutect2, varscan2
- LCT | c.3555C>A p.R1185= | Silent (SNP) | VAF 22/77 reads (29%) | called by muse, mutect2, varscan2
- LRP1B | c.5229G>T p.V1743= | Silent (SNP) | VAF 26/177 reads (15%) | called by muse, mutect2, varscan2
- LRP1B | c.5184G>T p.L1728= | Silent (SNP) | VAF 43/286 reads (15%) | called by muse, mutect2, varscan2
- MCF2 | c.489G>T p.L163= | Silent (SNP) | VAF 53/361 reads (15%) | called by muse, mutect2, varscan2
- MCHR1 | c.1203G>T p.G401= | Silent (SNP) | VAF 22/145 reads (15%) | called by muse, mutect2, varscan2
- MROH2A | c.1203C>A p.A401= | Silent (SNP) | VAF 39/262 reads (15%) | called by muse, mutect2, varscan2
- MS4A14 | c.519C>A p.A173= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as rs763176359; called by muse, mutect2
- MUC16 | c.9753C>A p.A3251= | Silent (SNP) | VAF 85/347 reads (24%) | catalogued as COSV67480164; called by muse, mutect2, varscan2
- MUC2 | c.1908G>A p.A636= | Silent (SNP) | VAF 21/216 reads (10%) | catalogued as rs774807711; called by muse, mutect2
- MXRA5 | c.5349C>A p.G1783= | Silent (SNP) | VAF 58/251 reads (23%) | catalogued as COSV54231458, COSV54252206; called by muse, mutect2, varscan2
- MYT1L | c.2032C>A p.R678= | Silent (SNP) | VAF 30/164 reads (18%) | catalogued as rs1271035520; called by muse, mutect2
- NRK | c.4272G>A p.K1424= | Silent (SNP) | VAF 63/287 reads (22%) | catalogued as COSV54601830, COSV99687912; called by muse, mutect2, varscan2
- PADI3 | c.576C>A p.A192= | Silent (SNP) | VAF 60/438 reads (14%) | called by muse, mutect2, varscan2
- PATJ | c.3345G>A p.K1115= | Silent (SNP) | VAF 29/370 reads (8%) | called by muse, mutect2
- PRR23C | c.711G>T p.P237= | Silent (SNP) | VAF 34/169 reads (20%) | called by muse, mutect2, varscan2
- PXDNL | c.2589G>T p.A863= | Silent (SNP) | VAF 42/287 reads (15%) | catalogued as COSV100681340; called by muse, mutect2, varscan2
- RPH3AL | c.150G>T p.A50= | Silent (SNP) | VAF 164/335 reads (49%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.867G>T p.L289= (on ENST00000265814 / NM_001198628.1; = p.L262= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 78/1060 reads (7%) | called by muse, mutect2
- RYR2 | c.12414C>A p.I4138= | Silent (SNP) | VAF 51/326 reads (16%) | called by muse, mutect2, varscan2
- SCN3A | c.3573C>A p.I1191= | Silent (SNP) | VAF 89/432 reads (21%) | called by muse, mutect2, varscan2
- SELENOT | c.12G>T p.L4= | Silent (SNP) | VAF 56/254 reads (22%) | called by muse, mutect2, varscan2
- SGCB | c.879G>T p.G293= | Silent (SNP) | VAF 112/816 reads (14%) | called by muse, mutect2, varscan2
- SHOX | c.753G>T p.A251= | Silent (SNP) | VAF 104/478 reads (22%) | called by muse, mutect2, varscan2
- SLC2A11 | c.498G>T p.T166= (on ENST00000345044 / NM_001024938.4; = p.T173= on NM_030807.5) | Silent (SNP) | VAF 16/113 reads (14%) | called by muse, mutect2, varscan2
- SLC4A4 | c.1485T>A p.T495= (on ENST00000264485 / NM_001098484.3; = p.T451= on NM_003759.4) | Silent (SNP) | VAF 71/756 reads (9%) | catalogued as rs375765213; called by muse, mutect2
- SLC6A18 | c.1230G>T p.L410= | Silent (SNP) | VAF 40/254 reads (16%) | catalogued as COSV57249672; called by muse, mutect2, varscan2
- SLIT1 | c.1884C>T p.I628= | Silent (SNP) | VAF 50/308 reads (16%) | catalogued as COSV56585027; called by muse, mutect2, varscan2
- SLITRK1 | c.1446G>C p.L482= | Silent (SNP) | VAF 57/198 reads (29%) | catalogued as COSV65676102; called by muse, mutect2, varscan2
- SPTA1 | c.4851G>T p.R1617= | Silent (SNP) | VAF 118/994 reads (12%) | called by mutect2, varscan2
- SPTA1 | c.3744G>T p.R1248= | Silent (SNP) | VAF 61/425 reads (14%) | catalogued as rs779014408; called by muse, mutect2, varscan2
- STK11 | c.432G>T p.P144= | Silent (SNP) | VAF 16/160 reads (10%) | catalogued as rs376788924; called by muse, varscan2
- TDRD15 | c.1075T>C p.L359= | Silent (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- TF | c.1924C>A p.R642= | Silent (SNP) | VAF 120/516 reads (23%) | catalogued as COSV53921994; called by muse, mutect2, varscan2
- TRBJ2-2 | c.48A>T p.V16= | Silent (SNP) | VAF 62/533 reads (12%) | called by muse, mutect2, varscan2
- UBASH3A | c.546C>T p.L182= | Silent (SNP) | VAF 24/206 reads (12%) | called by muse, mutect2, varscan2
- USH2A | c.2049A>T p.L683= | Silent (SNP) | VAF 65/354 reads (18%) | called by muse, mutect2, varscan2
- A2ML1 | c.483+11G>C | Intron (SNP) | VAF 54/340 reads (16%) | called by muse, mutect2, varscan2
- AC024940.1 | n.3229C>A | RNA (SNP) | VAF 86/425 reads (20%) | called by muse, mutect2, varscan2
- AC093155.3 | c.-18A>G | 5'UTR (SNP) | VAF 14/172 reads (8%) | called by muse, mutect2
- AC134312.1 | n.960C>A | RNA (SNP) | VAF 27/161 reads (17%) | called by muse, mutect2, varscan2
- ACAA2 | chr18:49814201 C>T | 5'Flank (SNP) | VAF 56/273 reads (21%) | catalogued as rs1225184406; called by muse, mutect2, varscan2
- AL445584.1 | chr9:42199643 C>A | 5'Flank (SNP) | VAF 37/257 reads (14%) | called by muse, mutect2, varscan2
- BIRC8 | n.1740A>T | RNA (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2
- CCDC7 | c.1802-10506G>T | Intron (SNP) | VAF 73/648 reads (11%) | called by muse, mutect2, varscan2
- CD33 | c.-37G>T | 5'UTR (SNP) | VAF 91/574 reads (16%) | catalogued as COSV99219946; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4963+12G>T | Intron (SNP) | VAF 27/87 reads (31%) | called by muse, varscan2
- CSMD3 | c.-44dup | 5'UTR (INS) | VAF 88/515 reads (17%) | called by mutect2, pindel, varscan2
- DCHS2 | n.8523C>G | RNA (SNP) | VAF 54/212 reads (25%) | called by muse, mutect2, varscan2
- DNAI2 | c.*36C>A | 3'UTR (SNP) | VAF 81/318 reads (25%) | called by muse, mutect2, varscan2
- DPP10 | c.61-244484G>T | Intron (SNP) | VAF 22/346 reads (6%) | called by muse, mutect2
- DST | c.4296+48G>A | Intron (SNP) | VAF 32/518 reads (6%) | called by muse, mutect2
- ERVV-1 | chr19:53009511 G>T | 5'Flank (SNP) | VAF 84/402 reads (21%) | called by muse, mutect2, varscan2
- FAM90A27P | n.578C>A | RNA (SNP) | VAF 47/267 reads (18%) | called by muse, varscan2
- GJC3 | c.*48C>T | 3'UTR (SNP) | VAF 35/446 reads (8%) | called by muse, mutect2
- LEO1 | c.1896+46G>A | Intron (SNP) | VAF 43/314 reads (14%) | catalogued as rs557657843; called by muse, mutect2, varscan2
- LINC00602 | n.1200C>A | RNA (SNP) | VAF 29/188 reads (15%) | called by muse, mutect2, varscan2
- LINC00602 | n.1201C>A | RNA (SNP) | VAF 29/194 reads (15%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+706T>A | Intron (SNP) | VAF 43/478 reads (9%) | called by muse, mutect2
- METTL25 | c.1478+20A>G | Intron (SNP) | VAF 10/52 reads (19%) | catalogued as rs1183066053; called by muse, mutect2
- MRRFP1 | n.369C>A | RNA (SNP) | VAF 45/186 reads (24%) | called by muse, mutect2, varscan2
- MTRR | c.365-28G>T | Intron (SNP) | VAF 86/574 reads (15%) | called by muse, mutect2, varscan2
- MUC1 | c.*258G>C | 3'UTR (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- MYO1F | c.-12C>A | 5'UTR (SNP) | VAF 62/250 reads (25%) | catalogued as COSV99547373; called by muse, mutect2, varscan2
- NBPF22P | n.989G>T | RNA (SNP) | VAF 153/670 reads (23%) | catalogued as rs551811186; called by muse, mutect2, varscan2
- OR52Z1 | n.411C>A | RNA (SNP) | VAF 44/257 reads (17%) | called by muse, mutect2, varscan2
- PDGFRA | c.1787-46del | Intron (DEL) | VAF 80/485 reads (16%) | called by mutect2, pindel, varscan2
- PLAC9 | c.-19G>T | 5'UTR (SNP) | VAF 27/202 reads (13%) | called by muse, mutect2, varscan2
- RBFOX1 | c.351+152569G>T | Intron (SNP) | VAF 63/277 reads (23%) | called by muse, mutect2, varscan2
- SHROOM4 | c.*631G>T | 3'UTR (SNP) | VAF 47/210 reads (22%) | called by muse, mutect2, varscan2
- SIGLEC17P | n.577G>T | RNA (SNP) | VAF 98/493 reads (20%) | called by muse, mutect2, varscan2
- SNORD115-25 | n.44G>T | RNA (SNP) | VAF 38/429 reads (9%) | catalogued as rs1326551949; called by muse, mutect2
- SRSF1 | c.552+24C>G | Intron (SNP) | VAF 61/251 reads (24%) | called by muse, mutect2, varscan2
- STRA6 | c.430+35C>G | Intron (SNP) | VAF 20/151 reads (13%) | called by muse, mutect2, varscan2
- TMEM161B | c.290-1002C>A | Intron (SNP) | VAF 24/268 reads (9%) | called by muse, mutect2
